Surgical pathology report (de-identified scan), TCGA case TCGA-36-2529, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2529-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

TCGA-36-2529

Case Number

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering
Physician:

Final Diagnosis:

Abdominal wall nodule and omentum resection showing metastatic poorly differentiated carcinoma, consistent with primary ovarian or peritoneal serous carcinoma.

Clinical History as Provided by Submitting Physician:

Pelvic mass

A. Abdominal wall nodules #2

B. Omentum #3

Specimens Received:

A: abdominal wall nodules #2

B: omentum #3

[page 2 of 2]
Gross Description:

Specimen is received in two containers both labelled with the patient's name.

Container "A" is labelled "abdominal wall nodules #2" and consists of a 2.5 x 1.2 x 0.6 cm fragment one on the side of which is lined by apparent peritoneum which shows irregular nodular bulging. The other face contains a small amount of fat and fibrous like tissue. Sections show nodular white tissue involving at least half of the specimen, the rest an admixture of fibrous tissue and fat. The sectioned specimen is submitted in toto as "A1".

Container "B" is labelled "omentum #3" and consists of two caked omental fragments. The total weight 292 grams, one fragment measuring 22.5 x 9.0 x 2.0 cm. The other 20.0 x 9.0 x 1.8 cm. Tissue has been obtained for the tumor bank. These fragments show thickening by white nodular tumor throughout. Representative sections submitted as "B1"-"B3".

Source: NCI Genomic Data Commons file 89692e62-40e8-480e-b70d-1b042b12f081 (TCGA-36-2529.D5D5F657-0CB5-454B-86BD-8599A808AB84.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).